Surgical pathology report (de-identified scan), TCGA case TCGA-KR-A7K2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University Of Michigan, specimen TCGA-KR-A7K2-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 7

SEX: M

ADM DATE:

BIRTHDATE

ICD-O-3

Carcinoma, hepatocellular &
cholangiocarcinoma combined
8190/3

Site: Liver C22.0

7/27/13

OPER DATE:

PROCEDURE: SPHS

Abdomen. Found with one dominant liver lesion consistent with hepatocellular carcinoma. Clinical Diagnosis: Hepatocellular carcinoma. Operative Procedure/Tissue Submitted: Open liver resection with intraop ultrasound.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 8

BIRTHDATE:

SEX: M
ADM DATE:

OPER DATE:

PROCEDURE: SPGD

1. "Gallbladder." Received in formalin in a medium container is a 9.1 x 3.5 x 2.7 cm gallbladder with smooth, unremarkable serosal surface. A 0.2 x 0.4 x 0.4 cm stump of cystic duct (probe patent) is present. The lumen of the gallbladder contains yellow, thick, viscous bile and seven black stones, ranging from 0.8 cm to 2.8 cm in greatest dimension. The gallbladder mucosa is dark yellow, velvety with patchy areas of erythema. The maximum gallbladder wall thickness is 0.2 cm. No areas of nodularity or masses are present.
1A. Standard gallbladder sections.

2. "Segment 8 liver mass, gross margins."

An 8.5 x 8.0 x 5.5 cm segment of liver with a 2.2 x 2.0 x 1.5 cm nodule, 1.1 cm to closest parenchymal margin (inked blue). The segment of liver has nodular capsule and parenchyma, without any other mass readily seen.

2A-2C. Mass with closest approach to margin.

2D. Remaining nodular parenchyma.

INTRAOPERATIVE GROSS DESCRIPTION:

2. Margin grossly negative (1.1 cm away).

I, _____ have reviewed and interpreted the frozen section material at the time it was requested.

Frozen section diagnosis is confirmed.

PROCEDURE: SPMI

LIVER: HEPATOCELLULAR CARCINOMA
=====

WAS THE TUMOR PREVIOUSLY TREATED?: No

TUMOR TYPE: Combined hepatocellular/cholangiocarcinoma

SINGLE OR MULTIPLE MASSES: Single

MAXIMUM DIAMETER OF LARGEST MASS: 2.2 cm

ARE THE MARGINS OF RESECTION FREE OF TUMOR?: Yes

VASCULAR INVASION?: No

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 9

BIRTHDATE:

SEX: M
ADM DATE:

OPER DATE:

INVASION THROUGH THE CAPSULE TO THE SEROSAL SURFACE?: No

LYMPH NODE METASTASES?: Unknown

DISTANT METASTASES?: Unknown

IS THE LIVER CIRRHOTIC?: Yes

IF CIRRHOTIC, WHAT IS THE CAUSE OF THE CIRRHOSIS?: Chronic hepatitis C infection.

pT1 NX

PROCEDURE: SPDX

1. Gallbladder, resection: Cholelithiasis.

2. Liver, segment 8, resection: Combined hepatocellular/cholangiocarcinoma (2.2 cm) confined to liver, arising in a background of hepatitis C cirrhosis. Margins of resection free. Please see TEMPLATE for details. See COMMENT.

COMMENT:

An immunohistochemical stain for CK7 highlights a cholangiocarcinoma component within the tumor.

This case was reviewed at our weekly gastrointestinal pathology conference.

I, _____ the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

FC:88304, 88307, 88329, 88342

"This test was developed and its performance characteristics determined by the _____ It has not been cleared or approved by the U.S. Food and Drug Administration. (The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ["CLIA"] as qualified to perform high complexity testing)."

Source: NCI Genomic Data Commons file b3ea5c58-9018-4627-90db-953896d7d957 (TCGA-KR-A7K2.5121C5D6-3BCB-4A0F-B18A-51BA4E87778B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).